Gene-level copy-number profile of tumor specimen TCGA-CM-6676-01A from TCGA case TCGA-CM-6676, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 82.7 years (30,223 days).
Specimen TCGA-CM-6676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.421c3727-1dfd-4904-8dcc-219b650d653c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CM-6676-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc5b3192-0dbe-43b0-b28b-e2bd8fd04910

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 3: 11,108; copy number 4: 27,459; copy number 5: 11,787; copy number 6: 5,491; copy number 7: 1,021; copy number 11: 986; copy number 12: 379; copy number 13: 208; copy number 15: 1,381.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-6676-01A-11D-1834-01): tumor purity 0.55, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,954 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:42,101,318–145,066,685, 1,589 genes, copy number 13–15 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 12 (broad region; genes not listed).
- chr18:27,932,879–28,177,946, 3 genes, copy number 12: CDH2, AC110015.1, AC006249.1.
- chr20:23,148,086–25,390,835, 68 genes, copy number 11 (within-gene range 3–11) (broad region; genes not listed).
- chr20:28,563,850–64,313,132, 918 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
